Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0EM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0EM-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex: (F Race: WHITE
Location:
Physician(s):

Specimen #: - - - -

Taken:
Received:
Reported:

****AMENDED****

ICD-0-3

Carcinoma, infiltrating ductal, NOS 850.3

Site: breast, NOS C50.9

1/26/11 *lw*

SPECIMEN:

A: SENTINEL LYMPH NODE B: RIGHT BREAST TISSUE
C: SUPERIOR MEDIAL BORDER

FINAL DIAGNOSIS:

- A. SENTINEL LYMPH NODE, BIOPSY:
- 1 LYMPH NODES NEGATIVE FOR TUMOR BY H&E.
- NEGATIVE FOR CYTOKERATIN BY IMMUNOHISTOCHEMISTRY.
- B. BREAST, RIGHT, LUMPECTOMY:
- INFLITRATIVE DUCTAL CARCINOMA WITH CRIBRIFORM PATTERN, WELL DIFFERENTIATED.
- SIZE: 1 CM.
- MARGINS NEGATIVE. NEAREST MARGIN, SUPERIOR, 2.0 MM
- NO LYMPHVASCULAR SPACE INVASION IDENTIFIED. - FIBROCYSTIC CHANGES TO INCLUDE FIBROSIS, CYSTS, AND APOCRINE METAPLASIA.
- MICROCALCIFICATIONS ASSOCIATED WITH BENIGN AND MALIGNANT BREAST TISSUE.
- AJCC T1bN0Mx.
- C. SUPERIOR MEDIAL BORDER TISSUE, EXCISION:
- BENIGN FIBROFATTY CONNECTIVE TISSUE.

**** Report Electronically Signed Out ****

CLINICAL DIAGNOSIS AND HISTORY:

-year-old white female with right breast cancer.

PRE-OPERATIVE DIAGNOSIS:

Right breast cancer.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION:

A. SENTINEL LYMPH NODE received fresh and consists of multiple irregular fragments of tan/yellow soft tissue measuring 3.0 x 2.0 x 0.5 cm in aggregate. The specimen is submitted in its entirety in two cassettes.

B. RIGHT BREAST TISSUE received fresh and consists of a 9.0 x 6.5 x 2.3 cm piece of fatty tissue oriented with sutures (one=medial, two=superior, three=anterior). Ink code: Red=medial and lateral, blue=superior, green=inferior, yellow=anterior, black=posterior. Sectioning reveals a 0.6 cm white/tan, ovoid mass with gritty cut surface, on sectioning-3.0 mm from superior/posterior margin. The remaining tissue is mostly fatty with admixed patches of white fibrous tissue. One section of each tumor and grossly normal fibrous tissue harvested for CBCP protocol; mirror images for Histology in cassettes B1 and B3 respectively. B2 tissue adjacent to tumor in the same plane. Additional representative sections are submitted in sequential order in 15 cassettes, the following pairs of cassettes representing one section in multiple cassettes: B4-B5, B7-B8, B9-B11. B7 and B8, and B9-B11 are tissue on either side of tumor.

C. SUPERIOR MEDIAL BORDER received in formalin and consists of one irregular shaped fragment of tan/yellow, lobular, fibrofatty adipose tissue measuring 3.0 x 2.4 x 1.5 cm. Orientation is not provided. The specimen is inked and serially section to reveal a yellow, lobular, glistening cut surface with no well-defined lesions or nodules identified. The specimen is submitted in its entirety in sequential order in three cassettes.

Source: NCI Genomic Data Commons file 5602b215-ec85-4576-9633-fed02893453e (TCGA-A2-A0EM.454CB5E9-3778-4666-9CED-913E08CB3615.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).